Somatic mutation profile of tumor specimen TCGA-G9-7525-01A (aliquot TCGA-G9-7525-01A-31D-2260-08) from TCGA case TCGA-G9-7525, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 64.3 years (23,481 days).
Specimen TCGA-G9-7525-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5421067d-acfe-4fd4-9298-4c87b3fc4705.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G9-7525-10A (Blood Derived Normal), aliquot TCGA-G9-7525-10A-01D-2260-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0ea295e5-2dce-4aaf-9931-7ee81c3fc557

The open-access MAF lists 33 somatic variants for this specimen: 27 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 22, Silent 6, Frame Shift Del 2, Nonsense Mutation 1, Translation Start Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGMO | c.739T>C p.F247L | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.882); catalogued as COSV61125477; called by muse, mutect2, varscan2
- ANKRD52 | c.1037C>T p.A346V | Missense Mutation (SNP) | VAF 76/194 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57287903; called by muse, mutect2, varscan2
- CCDC174 | c.1375A>G p.M459V | Missense Mutation (SNP) | VAF 37/92 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.365); catalogued as rs377188267; called by muse, mutect2, varscan2
- COL24A1 | c.4656A>C p.E1552D | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as rs761797687, COSV65315501; called by muse, mutect2, varscan2
- DAB2IP | c.1954G>A p.A652T (on ENST00000408936; = p.A624T on NM_032552.3) | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.259); catalogued as COSV52269499; called by muse, mutect2
- DHX15 | c.1316del p.P439Lfs*20 | Frame Shift Del (DEL) | VAF 15/108 reads (14%) | catalogued as COSV100391287, COSV61026742; called by mutect2, pindel, varscan2
- GDAP2 | c.1160T>G p.V387G | Missense Mutation (SNP) | VAF 4/53 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65613505; called by muse, mutect2
- IL25 | c.326G>A p.R109H | Missense Mutation (SNP) | VAF 13/128 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as rs767430645, COSV59306825; called by muse, mutect2, varscan2
- ITIH2 | c.323T>A p.V108D | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV64435523; called by muse, mutect2, varscan2
- IVNS1ABP | c.1878T>G p.Y626* | Nonsense Mutation (SNP) | VAF 55/162 reads (34%) | catalogued as COSV62252270; called by muse, mutect2, varscan2
- LTF | c.1196G>A p.C399Y | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51612665; called by muse, varscan2
- MUC5B | c.8514G>T p.R2838S | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV71596420; called by muse, mutect2, varscan2
- MYO15A | c.575G>A p.R192H | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.953); catalogued as rs777619303, COSV52767801; called by mutect2, varscan2
- NETO1 | c.892T>G p.F298V | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as COSV55005214; called by muse, mutect2, varscan2
- PLA2G4A | c.209T>G p.V70G | Missense Mutation (SNP) | VAF 20/194 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.221); catalogued as COSV66553738, COSV66557532; called by muse, mutect2, varscan2
- PRSS23 | c.889G>A p.V297I | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as rs1311139478, COSV54707816; called by muse, mutect2, varscan2
- PTPRG | c.3035G>A p.R1012H | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs764384969, COSV55665282; called by muse, mutect2
- RERE | c.4301C>T p.S1434F | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as COSV61952307; called by muse, mutect2, varscan2
- RTKN2 | c.1241G>A p.R414Q | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.205); catalogued as rs879435916, COSV59524851; called by muse, mutect2, varscan2
- SUFU | c.395C>G p.A132G | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV64016539; called by muse, mutect2, varscan2
- TMEM184B | c.340G>A p.V114I | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.81); PolyPhen benign (0.021); catalogued as rs201541960, COSV62674496; called by muse, mutect2, varscan2
- WDR72 | c.1661G>A p.R554Q | Missense Mutation (SNP) | VAF 47/171 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.164); catalogued as rs753883431, COSV64754695; called by muse, mutect2, varscan2
- YEATS2 | c.1430G>A p.R477Q | Missense Mutation (SNP) | VAF 14/186 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.778); catalogued as rs752273252, COSV59370830; called by muse, mutect2
- ZFP36L1 | c.547C>G p.R183G | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.26); catalogued as COSV60547442; called by muse, mutect2, varscan2
- AARS1 | c.2471del p.K824Rfs*19 | Frame Shift Del (DEL) | VAF 25/180 reads (14%) | called by mutect2, pindel, varscan2
- IGKV2D-30 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- VARS2 | c.244_246del p.V82del | In Frame Del (DEL) | VAF 21/88 reads (24%) | called by mutect2, pindel, varscan2
- ARMC3 | c.1401G>A p.A467= | Silent (SNP) | VAF 16/35 reads (46%) | catalogued as rs544182119, COSV53068762; called by muse, mutect2, varscan2
- PIK3CG | c.2103T>C p.S701= | Silent (SNP) | VAF 26/73 reads (36%) | catalogued as COSV63254524; called by muse, mutect2, varscan2
- SCNN1A | c.741G>A p.A247= | Silent (SNP) | VAF 16/150 reads (11%) | catalogued as rs574585318, COSV57437654; called by muse, mutect2
- SYNPO | c.1957A>C p.R653= (on ENST00000394243 / NM_001166208.2; = p.R409= on NM_007286.6) | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as COSV56943731; called by muse, mutect2, varscan2
- TPP1 | c.165G>A p.Q55= | Silent (SNP) | VAF 30/100 reads (30%) | catalogued as COSV55000232; called by muse, mutect2, varscan2
- ZNF484 | c.1935T>C p.F645= | Silent (SNP) | VAF 5/132 reads (4%) | catalogued as COSV60259944; called by muse, mutect2
